Somatic mutation profile of tumor specimen TCGA-BR-8286-01A (aliquot TCGA-BR-8286-01A-12D-2340-08) from TCGA case TCGA-BR-8286, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 49.2 years (17,966 days).
Specimen TCGA-BR-8286-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e88cc72-16cb-4db2-a296-810ebcfb395a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8286-10A (Blood Derived Normal), aliquot TCGA-BR-8286-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5545b17d-3028-4d60-8748-9d7d2ed658cb

The open-access MAF lists 157 somatic variants for this specimen: 108 protein-altering or splice-affecting, 46 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 46, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, Splice Region 2, In Frame Ins 2, Frame Shift Ins 1, Translation Start Site 1, Intron 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PREX2 | c.148T>G p.L50V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV55750189, COSV55751655, COSV99910567; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 48/77 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.7165A>T p.M2389L (on ENST00000272895 / NM_173076.3; = p.M2071L on NM_015657.3) | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs957495468, COSV55949659; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1316A>C p.K439T | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV52808917; called by muse, mutect2
- ADARB1 | c.1209G>T p.L403F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.788); catalogued as COSV62342121; called by muse, mutect2, varscan2
- ADGRB1 | c.4426C>T p.R1476W | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778880062, COSV60092020; called by muse, mutect2, varscan2
- ALDH1L1 | c.5A>C p.K2T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV56410838; called by muse, mutect2
- ALK | c.1414+1G>A p.X472_splice | Splice Site (SNP) | VAF 19/74 reads (26%) | catalogued as rs777414641, COSV66557567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD7 | c.24G>T p.W8C | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs924601572, COSV54553941; called by muse, mutect2, varscan2
- ARL13B | c.1124C>T p.P375L (on ENST00000394222 / NM_001174150.2; = p.P268L on NM_144996.4) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.406); catalogued as COSV57396173; called by muse, mutect2, varscan2
- ASTN1 | c.2561A>G p.N854S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as COSV56061785; called by muse, mutect2, varscan2
- ATP6V1C1 | c.639C>T p.S213= | Splice Region (SNP) | VAF 58/85 reads (68%) | catalogued as COSV67777288; called by muse, mutect2, varscan2
- ATXN2L | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV57365356, COSV57368514; called by muse, mutect2
- AVPI1 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65697300; called by muse, mutect2, varscan2
- BBX | c.1907T>C p.V636A | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57879276; called by muse, mutect2, varscan2
- CACNA1D | c.5204C>T p.S1735L (on ENST00000350061 / NM_001128840.3; = p.S1755L on NM_000720.4) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1461261149, COSV55437928; called by muse, mutect2
- CD5L | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63821114, COSV63822042; called by muse, varscan2
- CDH6 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV54064577; called by muse, mutect2, varscan2
- CDK13 | c.3241A>G p.T1081A | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as COSV51696467; called by muse, mutect2, varscan2
- CES2 | c.1268T>C p.V423A | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as COSV57696212; called by muse, mutect2, varscan2
- CFH | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV66405903, COSV66414066; called by muse, mutect2, varscan2
- CGN | c.1471A>G p.R491G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54968103; called by muse, mutect2, varscan2
- CHST6 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as COSV100178447, COSV59999450; called by muse, mutect2
- COL11A1 | c.4412del p.G1471Vfs*27 | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | catalogued as CM070056; called by mutect2, pindel, varscan2
- CORO2A | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs141466107; called by muse, mutect2, varscan2
- CRX | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 117/169 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV55757103; called by muse, mutect2, varscan2
- CSMD3 | c.3928T>A p.F1310I (on ENST00000297405 / NM_001363185.1; = p.F1206I on NM_052900.3) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV52106421; called by muse, mutect2, varscan2
- CYP11B1 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs771206231, COSV52824910; called by muse, mutect2, varscan2
- DAAM1 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62834199; called by muse, mutect2, varscan2
- DALRD3 | c.589G>A p.E197K (on ENST00000341949 / NM_001009996.3; = p.E30K on NM_018114.5) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV58243990, COSV58247280; called by muse, mutect2, varscan2
- DCLK1 | c.1985C>G p.A662G | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.271); catalogued as COSV55172511; called by muse, mutect2, varscan2
- DNAH5 | c.12599A>C p.K4200T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, mutect2, varscan2
- DNAH5 | c.6447T>G p.V2149= | Splice Region (SNP) | VAF 11/88 reads (13%) | catalogued as COSV54204864; called by muse, mutect2, varscan2
- DNAI2 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as rs765197781, COSV56756874; called by muse, mutect2, varscan2
- DUOX1 | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs149290661; called by muse, mutect2, varscan2
- EDC4 | c.4186G>A p.V1396M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs1242356021, COSV59301675; called by muse, mutect2, varscan2
- EDRF1 | c.1979A>C p.K660T (on ENST00000356792 / NM_001202438.2; = p.K626T on NM_015608.2) | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV61762491; called by muse, mutect2
- EMC3 | c.218T>C p.F73S | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55277345; called by muse, mutect2
- ETAA1 | c.2214G>T p.M738I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55472071; called by mutect2, varscan2
- GDF10 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs140410142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR150 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.414); catalogued as COSV66168164; called by muse, mutect2, varscan2
- GREB1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs192688544; called by muse, mutect2, varscan2
- GRIN1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV59292905; called by muse, mutect2, varscan2
- GRIN2A | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 98/193 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs534440095, COSV58020882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IER3IP1 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as rs1423240820, COSV56505332; called by muse, mutect2, varscan2
- IGFBP1 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.189); catalogued as COSV51874216; called by muse, mutect2, varscan2
- IGLL5 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.147); catalogued as rs777532054, COSV66538833; called by muse, mutect2, varscan2
- IKZF4 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56266807; called by muse, mutect2, varscan2
- IMPG2 | c.3046T>A p.F1016I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51973674; called by muse, mutect2, varscan2
- INPP4A | c.2431G>T p.E811* (on ENST00000074304 / NM_001134224.1; = p.E772* on NM_001566.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV50785493, COSV99302666; called by muse, mutect2
- KIF1B | c.1001C>T p.A334V (on ENST00000377086 / NM_001365952.1; = p.A328V on NM_015074.3) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55803683; called by muse, mutect2, varscan2
- KLHL13 | c.731T>G p.L244R | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53244796; called by muse, mutect2, varscan2
- KRT5 | c.647A>T p.E216V | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV52858953; called by muse, mutect2, varscan2
- LCE1C | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as rs755616563, COSV64218167; called by muse, mutect2, varscan2
- LRSAM1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs767351229, COSV55938308; called by muse, mutect2, varscan2
- LVRN | c.2161A>G p.I721V | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as rs755376576, COSV63496027; called by muse, mutect2, varscan2
- MCAM | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs369044315; called by muse, mutect2, varscan2
- MCOLN2 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV52293343, COSV52295407; called by muse, mutect2, varscan2
- MINDY4 | c.1459T>C p.S487P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV54671303; called by muse, mutect2, varscan2
- MXRA5 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs368706975, COSV54224299; called by muse, mutect2, varscan2
- NADSYN1 | c.1840A>T p.S614C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59810178; called by muse, mutect2, varscan2
- NOC2L | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs554175821, COSV58985985, COSV58987451; called by muse, mutect2, varscan2
- NRN1 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55205015; called by muse, mutect2, varscan2
- OBSCN | c.9547C>T p.R3183W | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs376064010; called by muse, mutect2, varscan2
- OR14C36 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV58600487; called by muse, mutect2, varscan2
- OR51A4 | c.565T>A p.L189M | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100985325; called by muse, mutect2
- OR51G2 | c.857T>G p.L286R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58991875; called by muse, mutect2, varscan2
- OR5B2 | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV56907555; called by muse, mutect2, varscan2
- PEG3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs570571376, COSV55625298; called by muse, mutect2, varscan2
- PKDREJ | c.2566A>G p.T856A | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53546575; called by muse, mutect2, varscan2
- PRR23B | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs1559938537, COSV61493188; called by muse, mutect2, varscan2
- PRSS45P | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV70576823; called by mutect2, varscan2
- PSG11 | c.607T>C p.F203L | Missense Mutation (SNP) | VAF 33/719 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs1177783014, COSV60453702; called by muse, mutect2
- PTPRN | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as rs1277149179, COSV55345711; called by muse, mutect2
- PTPRN2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs567734269, COSV66104639; called by muse, mutect2, varscan2
- PUM2 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV57577614; called by muse, mutect2, varscan2
- RASA1 | c.475_476del p.L159Gfs*20 | Frame Shift Del (DEL) | VAF 34/76 reads (45%) | catalogued as rs797044451; called by pindel, varscan2
- RBM47 | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 117/208 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV55930340; called by muse, mutect2, varscan2
- RFX2 | c.1493A>T p.Q498L | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV57939257; called by muse, mutect2, varscan2
- SCN11A | c.5237A>C p.K1746T | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV56565957; called by muse, mutect2, varscan2
- SEC14L4 | c.1084G>T p.V362F | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55398414; called by muse, mutect2, varscan2
- SERPINB12 | c.645+2T>C p.X215_splice | Splice Site (SNP) | VAF 19/72 reads (26%) | catalogued as rs1350908096, COSV54032155; called by muse, mutect2, varscan2
- SERPINB13 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54027348; called by muse, mutect2, varscan2
- SEZ6L2 | c.1207C>T p.R403W (on ENST00000308713 / NM_001114099.3; = p.R333W on NM_012410.4) | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1445187462, COSV58103041; called by muse, mutect2
- SHC4 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV60109507; called by muse, mutect2, varscan2
- SLC35A2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1557042884, COSV54429227; called by muse, mutect2, varscan2
- SMARCE1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs755039445, COSV52860581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN1 | c.1203A>C p.K401N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61685675, COSV61695075; called by muse, mutect2, varscan2
- STAG1 | c.3727T>C p.S1243P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV52601924; called by muse, mutect2, varscan2
- THADA | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57676325; called by muse, mutect2, varscan2
- TMEM72 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV67460154; called by muse, mutect2, varscan2
- TNNI2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV99425589; called by muse, mutect2, varscan2
- TPK1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV63637216; called by muse, mutect2, varscan2
- TPO | c.2093A>C p.N698T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV61095274; called by muse, mutect2, varscan2
- TPO | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV61095286, COSV61099964, COSV61110474; called by muse, mutect2, varscan2
- TTN | c.58375G>A p.V19459I (on ENST00000591111; = p.V12035I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | PolyPhen benign (0.001); catalogued as rs774240012, COSV59895730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VILL | c.2003G>A p.W668* | Nonsense Mutation (SNP) | VAF 65/136 reads (48%) | catalogued as COSV52182492; called by muse, mutect2, varscan2
- VN1R2 | c.1106G>T p.C369F | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV59037170; called by muse, mutect2, varscan2
- ZEB1 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs955193940, COSV58036779; called by muse, mutect2, varscan2
- ZNF266 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV63221494; called by muse, mutect2, varscan2
- ZNF292 | c.6457G>A p.E2153K | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV60535805; called by muse, mutect2, varscan2
- ZNF530 | c.319A>C p.I107L | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV60530907; called by muse, mutect2
- ZNF781 | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV62200378; called by muse, mutect2, varscan2
- ZWINT | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV59184861; called by muse, mutect2, varscan2
- ALG12 | c.738_740dup p.T247dup | In Frame Ins (INS) | VAF 31/163 reads (19%) | called by mutect2, pindel, varscan2
- PBLD | c.322_330dup p.G108_L110dup | In Frame Ins (INS) | VAF 17/60 reads (28%) | called by mutect2, varscan2
- PDE5A | c.2209_2219del p.E737Kfs*24 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- SLC4A10 | c.764dup p.N255Kfs*16 | Frame Shift Ins (INS) | VAF 15/32 reads (47%) | called by mutect2, pindel, varscan2
- APBB1 | c.1548C>A p.L516= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV54972914, COSV54975662; called by muse, mutect2, varscan2
- APOA4 | c.390G>A p.E130= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs771961939, COSV63360027; called by muse, mutect2, varscan2
- ATP2B3 | c.2689C>T p.L897= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV54840660, COSV54841127; called by muse, mutect2, varscan2
- BOP1 | c.225C>T p.D75= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs138704768; called by muse, mutect2, varscan2
- BRCA2 | c.2823G>C p.V941= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV66448424; called by muse, mutect2, varscan2
- CCAR1 | c.2919T>G p.S973= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56267347; called by muse, mutect2, varscan2
- CDH12 | c.2358G>A p.E786= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV66388978; called by muse, mutect2, varscan2
- CLTCL1 | c.2874C>T p.H958= | Silent (SNP) | VAF 57/151 reads (38%) | catalogued as rs782380909, COSV54225286; called by muse, mutect2, varscan2
- FAM155A | c.423C>T p.G141= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV65549777; called by muse, mutect2, varscan2
- FAM47B | c.1905A>G p.K635= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV61452573; called by muse, mutect2, varscan2
- FAM90A1 | c.453G>A p.P151= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs771226962, COSV56710105; called by muse, varscan2
- FKBP15 | c.843G>T p.V281= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV53031992; called by muse, mutect2, varscan2
- FLI1 | c.804G>T p.P268= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs1363259180, COSV55642670; called by muse, mutect2, varscan2
- GLI3 | c.3066G>A p.P1022= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1206623585, COSV67885002; called by muse, mutect2, varscan2
- HLA-DMB | c.558C>T p.Y186= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs771918401, COSV66870585; called by muse, mutect2, varscan2
- HLA-DQA2 | c.720C>A p.I240= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as rs1205526441, COSV66564610; called by muse, mutect2, varscan2
- HRNR | c.6126C>T p.H2042= | Silent (SNP) | VAF 129/1383 reads (9%) | catalogued as rs773303607, COSV100913784, COSV100914038; called by muse, mutect2, varscan2
- IGSF10 | c.4704T>C p.S1568= | Silent (SNP) | VAF 66/169 reads (39%) | catalogued as COSV56781816; called by muse, mutect2, varscan2
- KIAA1549L | c.2712G>T p.V904= (on ENST00000321505; = p.V1201= on NM_012194.3) | Silent (SNP) | VAF 79/164 reads (48%) | catalogued as COSV55769834, COSV55773564; called by muse, varscan2
- KIF1A | c.369C>T p.C123= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as rs757286820, COSV57483017; called by muse, mutect2, varscan2
- LAS1L | c.1152C>T p.P384= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV56706403; called by muse, mutect2, varscan2
- LCP1 | c.1650G>T p.L550= | Silent (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- LRFN1 | c.870C>T p.P290= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs746264800, COSV50434316; called by muse, mutect2, varscan2
- MAB21L1 | c.279A>C p.S93= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as COSV59761234; called by muse, mutect2, varscan2
- MAMLD1 | c.1402T>C p.L468= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV53372143; called by muse, mutect2
- MEIG1 | c.240C>T p.V80= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV65542376; called by muse, mutect2, varscan2
- MUC16 | c.23694A>T p.T7898= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- MUC17 | c.12306C>G p.T4102= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as COSV60280467; called by muse, mutect2, varscan2
- NCAPG2 | c.2424G>A p.G808= | Silent (SNP) | VAF 91/221 reads (41%) | catalogued as rs527387542, COSV51984845; called by muse, mutect2, varscan2
- NES | c.843C>T p.V281= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV63960390; called by muse, mutect2, varscan2
- NLRP9 | c.2103C>T p.D701= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV60459835; called by muse, mutect2, varscan2
- OR10G4 | c.112C>T p.L38= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as COSV57976649; called by muse, mutect2, varscan2
- OR5H14 | c.736T>C p.L246= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV101454095, COSV71193476; called by muse, mutect2, varscan2
- OR5T3 | c.600T>G p.S200= | Silent (SNP) | VAF 15/265 reads (6%) | catalogued as COSV100282706, COSV57379270; called by muse, mutect2
- PCLO | c.7395A>C p.T2465= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs754216468, COSV61616871; called by muse, mutect2, varscan2
- PCNX2 | c.1797C>G p.G599= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV50782425; called by muse, mutect2, varscan2
- PLXDC2 | c.1077T>C p.F359= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV65900917; called by muse, mutect2, varscan2
- PPP1R3F | c.705C>T p.D235= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs781863266, COSV50017701; called by muse, mutect2, varscan2
- PTPRD | c.4129T>C p.L1377= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV61929192, COSV61977408; called by muse, mutect2, varscan2
- ROGDI | c.555G>A p.P185= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs771793763, COSV59020737; called by muse, mutect2, varscan2
- SOGA3 | c.204T>C p.N68= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs1057403599, COSV64105108; called by muse, mutect2
- TLR4 | c.2442C>G p.A814= (on ENST00000355622 / NM_138554.5; = p.A774= on NM_003266.4) | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as COSV100842805, COSV62922449; called by muse, mutect2, varscan2
- TMEM184B | c.885G>A p.Q295= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV62671929; called by muse, mutect2, varscan2
- TNR | c.3213T>C p.Y1071= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV54871533; called by muse, mutect2, varscan2
- TTN | c.12232C>T p.L4078= (on ENST00000591111; = p.L4032= on NM_003319.4) | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as COSV59895757; called by muse, mutect2, varscan2
- ZNF181 | c.873A>G p.K291= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV67626296; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1224C>T | Intron (SNP) | VAF 41/171 reads (24%) | catalogued as rs373191717; called by muse, mutect2, varscan2
- TBC1D29P | n.2584C>T | RNA (SNP) | VAF 26/128 reads (20%) | catalogued as rs373002633; called by muse, mutect2, varscan2
- ZNF582 | c.-155G>A | 5'UTR (SNP) | VAF 5/28 reads (18%) | catalogued as rs780028117, COSV100018861; called by muse, mutect2, varscan2
